Somatic mutation profile of tumor specimen TCGA-13-1404-01A (aliquot TCGA-13-1404-01A-01W-0494-09) from TCGA case TCGA-13-1404, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 48.7 years (17,784 days).
Specimen TCGA-13-1404-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 859a2088-3f8d-4c13-9242-dbeadc878234.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1404-10A (Blood Derived Normal), aliquot TCGA-13-1404-10A-01W-0493-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb388eab-e280-42db-bfbc-2f93d12e4885

The open-access MAF lists 65 somatic variants for this specimen: 50 protein-altering or splice-affecting, 11 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 11, Nonsense Mutation 4, In Frame Del 3, Splice Site 3, RNA 2, 3'UTR 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 34/49 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC004922.1 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 46/58 reads (79%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.691); catalogued as COSV53555981; called by muse, mutect2, varscan2
- ARHGEF12 | c.2012C>G p.S671* | Nonsense Mutation (SNP) | VAF 33/76 reads (43%) | catalogued as COSV100755158; called by muse, mutect2, varscan2
- CEP162 | c.905C>G p.S302* | Nonsense Mutation (SNP) | VAF 22/54 reads (41%) | catalogued as COSV57618459; called by muse, mutect2, varscan2
- CEP290 | c.2308G>T p.A770S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.019); catalogued as COSV58350011, COSV58353529; called by muse, mutect2, varscan2
- CFAP77 | c.925C>A p.Q309K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV58008676; called by muse, mutect2, varscan2
- CILP | c.2491G>C p.E831Q | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56022780; called by muse, mutect2, varscan2
- COL19A1 | c.2591T>G p.L864W | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59568590; called by muse, mutect2, varscan2
- COL5A3 | c.3353G>C p.G1118A | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53408061, COSV53418984; called by muse, mutect2, varscan2
- DDB1 | c.2277+1G>T p.X759_splice | Splice Site (SNP) | VAF 42/110 reads (38%) | catalogued as COSV100074804; called by muse, mutect2, varscan2
- DDB1 | c.2277G>T p.Q759H | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.328); catalogued as COSV100074808; called by muse, mutect2, varscan2
- DEPDC5 | c.1245_1269del p.F415Lfs*35 | Frame Shift Del (DEL) | VAF 30/56 reads (54%) | catalogued as COSV56693489; called by mutect2, pindel, varscan2
- DNAH7 | c.5582G>T p.C1861F | Missense Mutation (SNP) | VAF 79/275 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.131); catalogued as COSV56756763; called by muse, mutect2, varscan2
- DSCAML1 | c.514A>T p.I172F (on ENST00000321322; = p.I112F on NM_020693.4) | Missense Mutation (SNP) | VAF 25/27 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV58385550; called by muse, mutect2, varscan2
- ESYT1 | c.1547C>G p.A516G | Missense Mutation (SNP) | VAF 74/184 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV57272035, COSV57276215; called by muse, mutect2, varscan2
- ETF1 | c.378G>C p.L126F | Missense Mutation (SNP) | VAF 84/209 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as COSV62127031; called by muse, mutect2, varscan2
- FAAH | c.776A>G p.N259S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV54543441; called by muse, mutect2
- FGD5 | c.3490G>A p.V1164I | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV53239457; called by muse, mutect2, varscan2
- HENMT1 | c.101A>T p.Q34L | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs11540221, COSV64230001; called by muse, mutect2, varscan2
- HIPK1 | c.616A>G p.K206E | Missense Mutation (SNP) | VAF 121/313 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65783787; called by muse, mutect2, varscan2
- IL25 | c.279-1G>A p.X93_splice | Splice Site (SNP) | VAF 60/130 reads (46%) | catalogued as COSV59305195; called by muse, mutect2, varscan2
- KIAA0319 | c.1734G>C p.Q578H | Missense Mutation (SNP) | VAF 240/771 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV65497147; called by muse, mutect2, varscan2
- LGALS12 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55369713; called by muse, mutect2, varscan2
- MICAL2 | c.3820C>T p.P1274S | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.017); catalogued as COSV56287895; called by muse, mutect2
- NR1H3 | c.1336C>T p.H446Y | Missense Mutation (SNP) | VAF 28/31 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV60621849; called by muse, mutect2, varscan2
- NUF2 | c.1191A>T p.E397D | Missense Mutation (SNP) | VAF 129/309 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV54842715; called by muse, mutect2, varscan2
- PLXNA4 | c.4997G>A p.G1666E | Missense Mutation (SNP) | VAF 582/1402 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58113383; called by muse, varscan2
- POLQ | c.6964C>G p.P2322A | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV51748135, COSV99951857; called by muse, mutect2, varscan2
- POT1 | c.427C>G p.H143D | Missense Mutation (SNP) | VAF 11/164 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as COSV100714130, COSV62928632; called by muse, mutect2
- PTCH1 | c.2963T>A p.V988E | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV59467531; called by muse, mutect2, varscan2
- PTER | c.698+1G>C p.X233_splice | Splice Site (SNP) | VAF 116/291 reads (40%) | catalogued as COSV54345068; called by muse, mutect2, varscan2
- RBM24 | c.347G>A p.G116E (on ENST00000379052 / NM_001143942.2; = p.G71E on NM_153020.2) | Missense Mutation (SNP) | VAF 90/279 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV59003160; called by muse, mutect2, varscan2
- RINT1 | c.455T>C p.I152T | Missense Mutation (SNP) | VAF 60/78 reads (77%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as rs1258669957, COSV57557855, COSV99994531; called by muse, mutect2, varscan2
- RNPEP | c.1035G>T p.W345C | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99821812; called by muse, mutect2
- SETD2 | c.5096C>T p.A1699V | Missense Mutation (SNP) | VAF 131/283 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57433214; called by muse, mutect2, varscan2
- SFTPB | c.515T>G p.L172R | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV60892914; called by muse, mutect2, varscan2
- SRF | c.1059G>T p.Q353H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as COSV54838054; called by muse, mutect2, varscan2
- TMEM126A | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 75/284 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52629137; called by muse, mutect2, varscan2
- TMTC4 | c.1294C>G p.L432V (on ENST00000376234 / NM_001350577.2; = p.L451V on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/60 reads (90%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV60891695; called by muse, mutect2, varscan2
- TPO | c.2500G>A p.D834N | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs368163933; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTC21B | c.2196C>A p.Y732* | Nonsense Mutation (SNP) | VAF 126/444 reads (28%) | catalogued as COSV54628853; called by muse, mutect2, varscan2
- USP26 | c.492A>T p.K164N | Missense Mutation (SNP) | VAF 26/695 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.334); catalogued as COSV100896737; called by muse, mutect2
- VEPH1 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 284/612 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV62877169; called by muse, mutect2, varscan2
- VHLL | c.238T>G p.Y80D | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV60554238; called by muse, mutect2, varscan2
- ZFHX3 | c.4090A>T p.K1364* | Nonsense Mutation (SNP) | VAF 12/156 reads (8%) | catalogued as COSV99214297; called by muse, mutect2
- ZFHX3 | c.4089G>T p.W1363C | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99214299; called by muse, mutect2
- ZNF275 | c.334C>A p.L112I | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.76); catalogued as COSV64704239; called by muse, mutect2, varscan2
- CCDC40 | c.1210_1224del p.M404_D408del | In Frame Del (DEL) | VAF 8/24 reads (33%) | called by mutect2, pindel, varscan2
- ITIH4 | c.2308_2331del p.T770_K777del | In Frame Del (DEL) | VAF 9/42 reads (21%) | called by mutect2, pindel
- METTL8 | c.386_388del p.S129del | In Frame Del (DEL) | VAF 196/810 reads (24%) | called by pindel, varscan2
- AMER1 | c.297G>T p.L99= | Silent (SNP) | VAF 174/370 reads (47%) | catalogued as COSV57656858, COSV57665990; called by muse, mutect2, varscan2
- ATP8B4 | c.1107A>T p.A369= | Silent (SNP) | VAF 72/181 reads (40%) | catalogued as COSV52711645; called by muse, mutect2, varscan2
- CARD10 | c.1818C>T p.S606= | Silent (SNP) | VAF 12/15 reads (80%) | catalogued as rs1170996084, COSV52655162; called by muse, mutect2, varscan2
- GDPD4 | c.1509C>T p.T503= | Silent (SNP) | VAF 22/232 reads (9%) | catalogued as COSV100265569; called by muse, mutect2
- KMT2C | c.12048C>T p.S4016= | Silent (SNP) | VAF 90/229 reads (39%) | catalogued as COSV51420798; called by muse, mutect2, varscan2
- MS4A7 | c.672A>T p.S224= | Silent (SNP) | VAF 68/534 reads (13%) | catalogued as COSV55729167; called by muse, mutect2, varscan2
- PLIN4 | c.2112T>C p.S704= (on ENST00000301286; = p.S719= on NM_001367868.2) | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs542160942, COSV56688655; called by muse, mutect2, varscan2
- SLC25A53 | c.387C>T p.A129= | Silent (SNP) | VAF 212/345 reads (61%) | catalogued as rs781873546, COSV62460380; called by muse, mutect2, varscan2
- TMEM71 | c.513G>C p.L171= (on ENST00000523829 / NM_001382398.1; = p.L152= on NM_144649.3) | Silent (SNP) | VAF 59/184 reads (32%) | catalogued as COSV63456837; called by muse, mutect2, varscan2
- TTN | c.4152T>C p.A1384= (on ENST00000591111; = p.A1338= on NM_003319.4) | Silent (SNP) | VAF 56/191 reads (29%) | catalogued as COSV59948819; called by muse, mutect2, varscan2
- ZSWIM8 | c.3759G>T p.G1253= (on ENST00000605216 / NM_001242487.2; = p.G1258= on NM_015037.3) | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV55213405; called by muse, mutect2, varscan2
- FOLH1B | n.1884C>A | RNA (SNP) | VAF 41/210 reads (20%) | called by muse, mutect2, varscan2
- KRT18P55 | n.941G>T | RNA (SNP) | VAF 83/109 reads (76%) | called by muse, mutect2, varscan2
- SLC30A9 | c.*1G>T | 3'UTR (SNP) | VAF 53/122 reads (43%) | catalogued as COSV100048454; called by muse, mutect2, varscan2
- TBX1 | chr22:19783010 C>T | 3'Flank (SNP) | VAF 2/8 reads (25%) | called by muse, mutect2
